Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3972, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3972-01A (Primary Tumor).

Diagnosis:

2. Resected section of colon (sigmoid) with an ulcerated colon carcinoma characterized histologically as a moderately differentiated colorectal adenocarcinoma, clearly extending up to 11 cm to the oral resection margin, measuring a max of 3 cm in diameter. Invasive spread of the tumor within all intestinal wall layers to the adjacent mesocolic fatty tissue.

Otherwise the intestinal wall has several pseudodiverticula with chronic scarring peridiverticulitis. The preparation has a tumor-free seminal vesicle attached aborally. Oral and aboral resection margins are tumor-free.

The tumor stage of the colon carcinoma described in (2) is therefore pT3, G2, R0.

Source: NCI Genomic Data Commons file 934895c6-0c0c-4ee2-be4a-eb97606e26e9 (TCGA-AA-3972.2562DE97-B8B4-4547-9E7F-4C0FAB6552B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).